Somatic mutation profile of tumor specimen BA2808D (aliquot aq-BA2808D) from BEATAML1.0 case 2300, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.4 years (20,592 days).
Specimen BA2808D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d203ae83-6d0b-41c3-a234-6b3e7f12ea40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2307D (Solid Tissue Normal), aliquot aq-BA2307D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a74ccf49-6450-422f-aa75-0636bb4f5b8f

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO1A | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 124/292 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs138932052; called by muse, varscan2
- PHRF1 | c.4931C>T p.T1644M (on ENST00000264555 / NM_001286581.2; = p.T1643M on NM_020901.4) | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as rs202141408; called by muse, mutect2, varscan2
- SPACA7 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.039); catalogued as COSV52098010; called by muse, mutect2, varscan2
- CALR3 | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CNTRL | c.5089G>C p.E1697Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ESPL1 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NFE2L3 | c.574A>G p.N192D | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OXR1 | c.671G>C p.S224T (on ENST00000442977 / NM_001198532.1; = p.S223T on NM_018002.3) | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- POLL | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- WAC | c.681C>A p.H227Q | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2
- BDKRB2 | c.1008C>A p.G336= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- MTCH2 | c.615C>G p.T205= | Silent (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- PDIA3 | c.168-2136G>T | Intron (SNP) | VAF 112/133 reads (84%) | catalogued as rs1461118763; called by muse, mutect2, varscan2
- TYR | c.-41A>G | 5'UTR (SNP) | VAF 64/118 reads (54%) | catalogued as rs886048744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
